Somatic mutation profile of tumor specimen C3L-00449-01 (aliquot CPT0007100009) from CPTAC case C3L-00449, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.4 years (21,705 days).
Specimen C3L-00449-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab18b87f-30b5-4a1f-9f8b-8d77e00db196.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00449-31 (Blood Derived Normal), aliquot CPT0002770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e69292f8-b3ba-4de8-adf4-a6982991998f

The open-access MAF lists 85 somatic variants for this specimen: 58 protein-altering or splice-affecting, 20 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 20, Nonsense Mutation 4, Intron 4, Frame Shift Ins 3, Frame Shift Del 2, In Frame Del 2, 5'UTR 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 112/309 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 246/602 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554898129, CM110132, COSV64288974, COSV64292774, COSV64296979; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 28/288 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADRA1D | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.062); catalogued as COSV65240263, COSV65241036; called by muse, mutect2, varscan2
- ALPK3 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99362206; called by muse, mutect2, varscan2
- ANKRD30B | c.2567C>T p.T856I | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.087); catalogued as rs772308610; called by muse, mutect2, varscan2
- BRINP1 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.222); catalogued as rs1281945379, COSV56314086; called by muse, mutect2, varscan2
- CDHR5 | c.2162C>T p.A721V (on ENST00000358353 / NM_001171968.2; = p.A727V on NM_021924.5) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs375605005; called by muse, mutect2, varscan2
- CLEC16A | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1388153357; called by muse, mutect2, varscan2
- COL11A2 | c.1298G>A p.R433Q (on ENST00000341947 / NM_080680.3; = p.R326Q on NM_080679.2) | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs762813373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPB41L4A | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs562929678, COSV54865021, COSV54866254; called by muse, mutect2, varscan2
- GALNT17 | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs767705580, COSV100353797, COSV61199127; called by muse, mutect2, varscan2
- H2BW2 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.277); catalogued as rs200690024; called by muse, mutect2, varscan2
- MACF1 | c.17872C>T p.R5958* (on ENST00000372915; = p.R4003* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 48/254 reads (19%) | catalogued as rs768150870; called by muse, mutect2, varscan2
- MAP3K5 | c.2024A>G p.Y675C | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372654498; called by muse, mutect2, varscan2
- NKX2-5 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as rs772542981; called by muse, mutect2, varscan2
- NPHP1 | c.2098G>A p.A700T (on ENST00000393272 / NM_207181.4; = p.A701T on NM_000272.5) | Missense Mutation (SNP) | VAF 67/353 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as rs201077898; called by muse, mutect2, varscan2
- ORMDL2 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs780407310; called by muse, mutect2, varscan2
- PIANP | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as rs1177825810, COSV100272416; called by muse, mutect2, varscan2
- PPP1R21 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs139240031; called by muse, mutect2
- PROX1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV54776614; called by muse, mutect2
- PSAPL1 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.27); catalogued as rs149921436; called by muse, mutect2, varscan2
- SH3RF2 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 40/271 reads (15%) | catalogued as rs745318390, COSV63040110; called by muse, mutect2, varscan2
- TAF1 | c.3080T>G p.F1027C (on ENST00000373790 / NM_138923.4; = p.F1048C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52122044; called by muse, mutect2, varscan2
- TENM3 | c.7804G>A p.A2602T | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as rs1016563035, COSV69313206; called by muse, mutect2, varscan2
- THBS1 | c.2947G>A p.G983S | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52956089; called by muse, mutect2
- ULK1 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs749305256; called by muse, mutect2
- WDR77 | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.48); catalogued as COSV99330820; called by muse, mutect2, varscan2
- WNK2 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52937403; called by muse, mutect2, varscan2
- AIDA | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- APOOL | c.221G>C p.C74S | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARID5B | c.1535dup p.D513Rfs*15 | Frame Shift Ins (INS) | VAF 47/243 reads (19%) | called by mutect2, pindel, varscan2
- ATP6V1A | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- BDP1 | c.4891G>A p.V1631I | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- BUB3 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- C1QL4 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2
- C6orf141 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.101); called by muse, varscan2
- C6orf141 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.06); called by muse, varscan2
- CALB1 | c.689_691del p.N230del | In Frame Del (DEL) | VAF 30/140 reads (21%) | called by pindel, varscan2
- CASK | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDC27 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- CREBBP | c.5303G>A p.R1768H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CTCF | c.1032_1034del p.K344_H345delinsN | In Frame Del (DEL) | VAF 37/306 reads (12%) | called by mutect2, pindel, varscan2
- DNAJB12 | c.1190G>T p.C397F (on ENST00000338820; = p.C363F on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- EDRF1 | c.690A>C p.E230D | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF2S3B | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EXTL3 | c.2309dup p.F771Lfs*24 | Frame Shift Ins (INS) | VAF 60/359 reads (17%) | called by mutect2, pindel, varscan2
- F11R | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- MID1 | c.1919C>A p.T640N | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- MKI67 | c.3212C>T p.S1071F | Missense Mutation (SNP) | VAF 61/466 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PPP2CA | c.910_922del p.T304Sfs*19 | Frame Shift Del (DEL) | VAF 21/186 reads (11%) | called by mutect2, pindel, varscan2
- PRKCH | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- PROKR2 | c.344T>G p.V115G | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUV39H1 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SYNE1 | c.23666A>C p.Q7889P (on ENST00000367255 / NM_182961.4; = p.Q7818P on NM_033071.3) | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM63B | c.2259del p.R754Efs*54 | Frame Shift Del (DEL) | VAF 26/122 reads (21%) | called by mutect2, pindel, varscan2
- VIL1 | c.779A>G p.D260G | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- YLPM1 | c.2946dup p.K983* | Frame Shift Ins (INS) | VAF 33/198 reads (17%) | called by mutect2, pindel, varscan2
- AATK | c.4014G>T p.T1338= (on ENST00000326724 / NM_001080395.3; = p.T1235= on NM_004920.2) | Silent (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.2853G>A p.P951= | Silent (SNP) | VAF 30/190 reads (16%) | catalogued as rs762389970, COSV65891609; called by muse, mutect2, varscan2
- AHNAK2 | c.13206C>T p.D4402= | Silent (SNP) | VAF 51/294 reads (17%) | catalogued as rs778375938; called by muse, mutect2, varscan2
- ANTXRL | c.885C>T p.S295= | Silent (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- BOP1 | c.1185G>A p.P395= | Silent (SNP) | VAF 34/180 reads (19%) | catalogued as rs1285463533; called by muse, mutect2, varscan2
- CTNNBIP1 | c.228G>A p.T76= | Silent (SNP) | VAF 21/169 reads (12%) | catalogued as rs777597196; called by muse, mutect2, varscan2
- DLK2 | c.1056G>A p.A352= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs761699614; called by muse, mutect2, varscan2
- DSP | c.1284C>T p.I428= | Silent (SNP) | VAF 40/269 reads (15%) | catalogued as rs867843559, COSV65794622; called by muse, mutect2, varscan2
- EDN3 | c.186C>T p.G62= | Silent (SNP) | VAF 68/426 reads (16%) | catalogued as rs1256693550, COSV61108832; called by muse, mutect2, varscan2
- EMD | c.162C>T p.S54= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- EOLA1 | c.132T>A p.A44= | Silent (SNP) | VAF 22/328 reads (7%) | called by muse, mutect2
- FMR1 | c.1380C>T p.S460= | Silent (SNP) | VAF 35/227 reads (15%) | called by muse, mutect2, varscan2
- GPR119 | c.156C>G p.T52= | Silent (SNP) | VAF 31/169 reads (18%) | called by muse, mutect2, varscan2
- KIR3DL1 | c.672T>C p.P224= | Silent (SNP) | VAF 21/212 reads (10%) | called by muse, mutect2
- MAN2B2 | c.1968G>A p.A656= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs538817825; called by muse, mutect2
- POLE3 | c.253T>C p.L85= | Silent (SNP) | VAF 34/190 reads (18%) | catalogued as rs771009190; called by muse, mutect2, varscan2
- RBM14 | c.381C>T p.A127= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs1303418529, COSV100036632; called by muse, mutect2
- TACC3 | c.1623G>A p.L541= | Silent (SNP) | VAF 28/178 reads (16%) | catalogued as rs369086652; called by muse, mutect2, varscan2
- UNC13A | c.2760C>T p.S920= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs371816774; called by muse, mutect2, varscan2
- ZNF497 | c.369G>A p.Q123= | Silent (SNP) | VAF 45/273 reads (16%) | called by muse, mutect2, varscan2
- CFAP46 | c.3219+158C>A | Intron (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- DLG2 | c.205-65783G>A | Intron (SNP) | VAF 47/233 reads (20%) | catalogued as rs45482499, COSV54634359, COSV99717820; called by muse, mutect2, varscan2
- GPHN | chr14:66505310 A>C | 5'Flank (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- KIR3DX1 | n.522G>A | RNA (SNP) | VAF 37/271 reads (14%) | catalogued as rs759904970; called by muse, mutect2, varscan2
- NRXN1 | c.3365-109845A>T | Intron (SNP) | VAF 53/359 reads (15%) | called by muse, mutect2, varscan2
- PARD3B | c.2630+150G>A | Intron (SNP) | VAF 27/183 reads (15%) | called by muse, mutect2, varscan2
- PPM1M | c.-131G>A | 5'UTR (SNP) | VAF 14/99 reads (14%) | catalogued as rs1205719046; called by muse, mutect2, varscan2
